Somatic mutation profile of tumor specimen TCGA-EJ-5519-01A (aliquot TCGA-EJ-5519-01A-01D-1576-08) from TCGA case TCGA-EJ-5519, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.8 years (23,669 days).
Specimen TCGA-EJ-5519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74119405-66f8-47ba-913e-dffeaeb2d0c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5519-10A (Blood Derived Normal), aliquot TCGA-EJ-5519-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0f646da-61af-45a3-b9e7-1c59d9f08679

The open-access MAF lists 85 somatic variants for this specimen: 60 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 45, Silent 25, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 3, Translation Start Site 1, Splice Site 1, In Frame Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD10 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 30/489 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV58162923; called by muse, mutect2
- ADNP | c.1286C>G p.A429G | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs922810666, COSV62426867; called by muse, mutect2, varscan2
- ATG13 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.815); catalogued as COSV56322048; called by muse, mutect2, varscan2
- B3GNT3 | c.856G>C p.A286P | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV57953323, COSV57953944; called by muse, mutect2, varscan2
- BET1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55993676; called by muse, mutect2, varscan2
- CEP350 | c.2378C>G p.T793S | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV62609417; called by muse, mutect2, varscan2
- CFAP54 | c.6528+2T>C p.X2176_splice | Splice Site (SNP) | VAF 28/57 reads (49%) | catalogued as COSV61575077; called by muse, mutect2, varscan2
- CHAF1A | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.519); catalogued as rs375548057; called by muse, mutect2, varscan2
- DCSTAMP | c.742A>G p.T248A | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52580069; called by muse, mutect2
- DNAJB11 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.672); catalogued as rs772358902, COSV54003750; called by muse, mutect2, varscan2
- DPP6 | c.1885G>A p.D629N (on ENST00000377770 / NM_001364500.2; = p.D567N on NM_001936.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as COSV59643521; called by muse, mutect2, varscan2
- EIF2D | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs782724706, COSV55114763; called by muse, mutect2
- ESRP1 | c.710C>G p.S237* | Nonsense Mutation (SNP) | VAF 37/143 reads (26%) | catalogued as COSV64409931, COSV64412568; called by muse, mutect2, varscan2
- FAM214A | c.3019A>C p.N1007H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV55927102; called by muse, mutect2, varscan2
- GNB5 | c.560A>G p.K187R (on ENST00000261837 / NM_016194.4; = p.K145R on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.991); catalogued as COSV55901199; called by muse, mutect2, varscan2
- GUCY2F | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 101/146 reads (69%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV54308274; called by muse, mutect2, varscan2
- KCND3 | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV56189273; called by muse, mutect2, varscan2
- KCTD10 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as COSV57328233; called by muse, mutect2, varscan2
- KIF16B | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 80/281 reads (28%) | catalogued as COSV61714442; called by muse, mutect2, varscan2
- LRRC14 | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV52882673; called by muse, mutect2, varscan2
- LRRC3B | c.380G>C p.S127T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.194); catalogued as COSV67522619; called by muse, mutect2, varscan2
- LY9 | c.483G>C p.M161I | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54437649; called by muse, mutect2
- MFAP4 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV55191823; called by muse, mutect2, varscan2
- MOXD1 | c.399C>A p.D133E | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60949128; called by muse, mutect2, varscan2
- MYCBP2 | c.10310G>T p.R3437I (on ENST00000357337; = p.R3475I on NM_015057.5) | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62038285; called by muse, mutect2, varscan2
- NAA20 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV58549307; called by muse, varscan2
- NOTCH2 | c.3505G>A p.G1169S | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56705290; called by muse, mutect2, varscan2
- NUDCD1 | c.840G>C p.W280C | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53460491; called by muse, mutect2
- NUP43 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1426810144, COSV61191351; called by muse, mutect2, varscan2
- OR1J1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52239876; called by muse, mutect2, varscan2
- OR7A5 | c.959G>T p.*320Lext*9 | Nonstop Mutation (SNP) | VAF 68/217 reads (31%) | catalogued as COSV59235547; called by muse, mutect2, varscan2
- PCDHA12 | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs1554167867, COSV56543397; called by mutect2, varscan2
- PDE2A | c.1448C>A p.A483D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV57813286; called by muse, mutect2, varscan2
- PDP2 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61241545; called by muse, mutect2, varscan2
- PFKP | c.2067C>G p.I689M | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.057); catalogued as COSV56539382; called by muse, mutect2, varscan2
- PIAS3 | c.724A>G p.I242V | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.728); catalogued as COSV65172061; called by muse, mutect2
- RINT1 | c.1068G>C p.Q356H | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57560630; called by muse, mutect2
- RSPRY1 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV68028620; called by muse, mutect2
- SACS | c.8153C>G p.A2718G | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV66546395; called by muse, mutect2, varscan2
- SEPTIN4 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 15/122 reads (12%) | catalogued as rs996393442, COSV57899453; called by muse, mutect2, varscan2
- SIPA1L3 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs200090564, COSV55923752; called by muse, mutect2, varscan2
- STK36 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1446434304, COSV55309568; called by muse, mutect2, varscan2
- STK4 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV65671998; called by muse, mutect2
- SYNE1 | c.15394A>T p.T5132S (on ENST00000367255 / NM_182961.4; = p.T5061S on NM_033071.3) | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV55095729; called by muse, mutect2, varscan2
- TANGO6 | c.2855C>G p.S952* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs775658363, COSV55772566; called by muse, mutect2
- TENM4 | c.2063A>T p.N688I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV53667782; called by muse, mutect2, varscan2
- THEMIS2 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61078423; called by muse, mutect2, varscan2
- THTPA | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs751934784, COSV55339375; called by muse, mutect2, varscan2
- TLN1 | c.4006G>T p.A1336S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.264); catalogued as COSV59211616; called by muse, mutect2
- TUBD1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as rs373399411; called by muse, mutect2, varscan2
- VWC2L | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV56978754; called by muse, mutect2
- XIRP1 | c.4330C>A p.P1444T | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV61140907; called by muse, mutect2, varscan2
- CFAP74 | c.4651A>T p.K1551* | Nonsense Mutation (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- DCLRE1C | c.1233del p.H412Tfs*7 (on ENST00000378278 / NM_001350965.2; = p.H297Tfs*7 on NM_022487.4) | Frame Shift Del (DEL) | VAF 17/122 reads (14%) | called by mutect2, pindel, varscan2
- FAM111A | c.1439dup p.Q481Afs*3 | Frame Shift Ins (INS) | VAF 66/208 reads (32%) | called by mutect2, varscan2
- FXR1 | c.899dup p.N300Kfs*20 | Frame Shift Ins (INS) | VAF 35/128 reads (27%) | called by mutect2, pindel, varscan2
- GANAB | c.437_438insGTCC p.Y147Sfs*14 | Frame Shift Ins (INS) | VAF 45/168 reads (27%) | called by mutect2, pindel, varscan2
- ROCK1 | c.31_33dup p.F11dup | In Frame Ins (INS) | VAF 41/163 reads (25%) | called by mutect2, pindel, varscan2
- SERINC1 | c.1023del p.N342Ifs*3 | Frame Shift Del (DEL) | VAF 46/198 reads (23%) | called by pindel, varscan2*
- ZZZ3 | c.317_318del p.R106Kfs*14 | Frame Shift Del (DEL) | VAF 104/399 reads (26%) | called by pindel, varscan2
- ABCA13 | c.7503T>C p.T2501= | Silent (SNP) | VAF 34/471 reads (7%) | catalogued as COSV71293989; called by muse, mutect2
- ABCG5 | c.1902T>A p.L634= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV53185229; called by muse, mutect2, varscan2
- ASAP1 | c.222G>C p.V74= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV63054195; called by muse, mutect2, varscan2
- BARD1 | c.747C>T p.I249= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs746551077, COSV53617229; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH17 | c.2142C>T p.N714= | Silent (SNP) | VAF 45/168 reads (27%) | catalogued as rs147500239; called by muse, mutect2, varscan2
- EBF2 | c.861G>T p.G287= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs778266031, COSV68780492; called by muse, mutect2, varscan2
- FLG | c.12069T>C p.D4023= | Silent (SNP) | VAF 73/275 reads (27%) | catalogued as rs1478099184, COSV64248556; called by muse, mutect2, varscan2
- GRM4 | c.375G>A p.A125= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs199504271; called by muse, mutect2, varscan2
- HMCN1 | c.8970T>G p.G2990= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV54939446; called by muse, mutect2, varscan2
- KRTAP10-1 | c.414G>A p.Q138= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as COSV59979020; called by muse, mutect2, varscan2
- MTMR7 | c.1032G>A p.R344= | Silent (SNP) | VAF 40/272 reads (15%) | catalogued as COSV51667213; called by mutect2, varscan2
- NUP107 | c.580C>A p.R194= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV57497824, COSV57497936; called by muse, mutect2, varscan2
- NYAP2 | c.972G>A p.P324= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs757942977, COSV56004713; called by muse, mutect2, varscan2
- OR7C1 | c.111C>G p.V37= | Silent (SNP) | VAF 7/166 reads (4%) | catalogued as COSV50184382; called by muse, mutect2
- PEG10 | c.540T>C p.S180= (on ENST00000482108 / NM_001040152.2; = p.S214= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/329 reads (11%) | catalogued as COSV71788673; called by muse, mutect2
- PEMT | c.384G>A p.A128= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs772155020, COSV55134074; called by muse, mutect2, varscan2
- PPEF2 | c.72C>T p.A24= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV54426098; called by muse, mutect2, varscan2
- PSMG2 | c.186G>T p.A62= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as COSV50870199; called by muse, mutect2, varscan2
- RABEP1 | c.1449A>G p.Q483= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as rs1567544082, COSV52588263; called by muse, mutect2, varscan2
- RASGRP3 | c.342C>T p.H114= | Silent (SNP) | VAF 98/277 reads (35%) | catalogued as rs1369319964, COSV67825037; called by muse, mutect2, varscan2
- RCBTB1 | c.924C>T p.Y308= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV51636869; called by muse, mutect2
- RESF1 | c.1926C>T p.G642= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV57025462; called by muse, mutect2, varscan2
- SF3A1 | c.1122A>G p.T374= | Silent (SNP) | VAF 65/183 reads (36%) | catalogued as COSV53171179; called by muse, mutect2, varscan2
- SLC38A2 | c.897G>C p.L299= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV56746400; called by muse, mutect2, varscan2
- USP2 | c.1305C>T p.F435= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs767580588, COSV52731041; called by muse, mutect2, varscan2
